Somatic mutation profile of tumor specimen TCGA-D1-A161-01A (aliquot TCGA-D1-A161-01A-11D-A122-09) from TCGA case TCGA-D1-A161, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G1; Age at diagnosis: 78.6 years (28,695 days).
Specimen TCGA-D1-A161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb2888b1-40be-4606-a39a-7abded676120.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A161-10A (Blood Derived Normal), aliquot TCGA-D1-A161-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c20c007a-7aa8-47b8-b6aa-3ec2e5bbbb6a

The open-access MAF lists 96 somatic variants for this specimen: 70 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 56, Silent 26, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 3, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 44/73 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 55/191 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 39/126 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV55911087; called by muse, mutect2, varscan2
- PIK3R1 | c.1214_1216del p.I405del (on ENST00000521381 / NM_181523.3; = p.I135del on NM_181504.4) | In Frame Del (DEL) | VAF 37/99 reads (37%) | hotspot (GDC flag); called by pindel, varscan2
- ABCA9 | c.4348G>T p.G1450W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761637364, COSV60630313; called by muse, mutect2, varscan2
- ANKRD52 | c.2830A>C p.I944L | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV57287100; called by muse, mutect2, varscan2
- ATP6V1B1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782603735, COSV52271364; called by muse, mutect2, varscan2
- ATRX | c.4539G>T p.E1513D | Missense Mutation (SNP) | VAF 204/545 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.837); catalogued as COSV64882331; called by muse, varscan2
- BCHE | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs960952225, COSV52261188; called by muse, mutect2, varscan2
- CASP8 | c.332_334del p.E111del (on ENST00000432109 / NM_033355.3; = p.E143del on NM_001228.4) | In Frame Del (DEL) | VAF 131/353 reads (37%) | catalogued as rs763516126; called by pindel, varscan2
- CFAP54 | c.6963C>G p.Y2321* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV61574795; called by muse, mutect2, varscan2
- COL7A1 | c.7984G>A p.G2662R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56477174; called by muse, mutect2, varscan2
- CPEB4 | c.1420G>T p.V474L | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54175623; called by muse, mutect2, varscan2
- CSF1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV60035164; called by muse, mutect2, varscan2
- CTCF | c.1168_1169insGT p.D390Gfs*6 | Frame Shift Ins (INS) | VAF 42/115 reads (37%) | catalogued as COSV50508452; called by mutect2, pindel, varscan2
- DCHS1 | c.5843T>A p.I1948N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100202669; called by muse, mutect2
- DHX34 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769467907, COSV60897855; called by muse, mutect2, varscan2
- DNAH17 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs377562551; called by muse, mutect2, varscan2
- DOCK3 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745982691, COSV56521395; called by muse, mutect2, varscan2
- DOCK4 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 108/315 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs147439564; called by muse, mutect2, varscan2
- FAM13A | c.1726+1G>C p.X576_splice | Splice Site (SNP) | VAF 68/168 reads (40%) | catalogued as COSV52011809; called by muse, mutect2, varscan2
- FCHO1 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761547319, COSV53184960; called by muse, mutect2, varscan2
- GIMAP5 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs750389982, COSV57530422; called by muse, mutect2, varscan2
- GRID1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs770555419, COSV60049348; called by muse, mutect2, varscan2
- HTR2C | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52222417; called by muse, mutect2, varscan2
- IGSF22 | c.2258A>T p.D753V (on ENST00000319338; = p.D854V on NM_173588.4) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.58); catalogued as COSV60038066; called by muse, mutect2, varscan2
- IL31RA | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 123/264 reads (47%) | catalogued as rs144337484; called by muse, mutect2, varscan2
- IRAK3 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54159484, COSV54164983; called by muse, mutect2, varscan2
- ITGB2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs752687370, COSV56612876; called by muse, mutect2, varscan2
- LATS1 | c.2695_2704del p.A899Tfs*5 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | catalogued as COSV53598513; called by mutect2, pindel, varscan2
- MDN1 | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as rs139594379, COSV101021815, COSV65529107; called by muse, mutect2, varscan2
- MECOM | c.613C>A p.R205S (on ENST00000468789 / NM_001105078.4; = p.R393S on NM_004991.4) | Missense Mutation (SNP) | VAF 236/642 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52963046, COSV52964249, COSV52973072; called by muse, mutect2, varscan2
- MOGAT2 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs61897998, COSV52221205; called by muse, mutect2, varscan2
- MON1A | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV56562554; called by muse, mutect2, varscan2
- MYH7B | c.4516C>T p.R1506W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs770198405, COSV52684026; called by muse, mutect2, varscan2
- N4BP2 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV54706129; called by muse, mutect2, varscan2
- NCOR2 | c.4540A>G p.T1514A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV62303308; called by muse, mutect2
- NSUN5 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99392582; called by muse, mutect2
- OGDHL | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs575253550, COSV65100800; called by muse, mutect2, varscan2
- OR5B21 | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV64482217; called by muse, mutect2, varscan2
- PABPC5 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.065); catalogued as COSV57040474; called by muse, mutect2
- PADI3 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64935283; called by muse, mutect2, varscan2
- PRODH2 | c.1587del p.G530Dfs*? (on ENST00000301175; = p.G454Dfs*? on NM_021232.2 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as COSV56561754; called by mutect2, pindel
- PRPF8 | c.5494C>T p.R1832C | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262553; called by muse, mutect2, varscan2
- PTPRO | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55520877; called by muse, mutect2, varscan2
- RIPOR3 | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs557718859, COSV50400886; called by muse, mutect2, varscan2
- RNF43 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs763974538, COSV68459639; called by muse, mutect2
- RNGTT | c.1178A>C p.H393P | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.601); catalogued as COSV55659003; called by muse, mutect2, varscan2
- RTL5 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV65454741; called by muse, mutect2, varscan2
- SLC18A3 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60331906; called by muse, mutect2, varscan2
- SLC30A8 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1267353057, COSV69969913; called by muse, mutect2, varscan2
- SLC7A5 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334751026, COSV55366569; called by muse, mutect2, varscan2
- SLITRK1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1484219521, COSV65677270; called by muse, mutect2, varscan2
- SLITRK2 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV59428183; called by muse, mutect2, varscan2
- SMAD7 | c.957C>A p.C319* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV50989600, COSV50991705; called by muse, mutect2, varscan2
- SREBF2 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs774875916, COSV63332306; called by muse, mutect2, varscan2
- SSTR4 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs377034050; called by muse, mutect2, varscan2
- ST13 | c.505C>G p.R169G | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs749727037, COSV53422354, COSV53423494; called by muse, mutect2, varscan2
- TAS2R10 | c.349A>T p.I117L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV53701605, COSV99555616; called by muse, mutect2, varscan2
- TM4SF1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV59525444, COSV59525888; called by muse, mutect2, varscan2
- TRIM3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61985418; called by muse, mutect2, varscan2
- UBA6 | c.2860A>G p.I954V | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV59180654; called by muse, mutect2, varscan2
- VPS37B | c.57C>G p.N19K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV57359769, COSV57360706; called by muse, mutect2, varscan2
- WDR33 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs777428982, COSV59254819; called by muse, mutect2, varscan2
- ZNF273 | c.1091A>G p.H364R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1192807612, COSV60400422; called by muse, mutect2, varscan2
- ZNF81 | c.570T>G p.H190Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58578280; called by muse, mutect2, varscan2
- IRF2BP2 | c.1130dup p.P378Afs*39 | Frame Shift Ins (INS) | VAF 75/199 reads (38%) | called by mutect2, pindel, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | called by mutect2, varscan2
- PTEN | c.904_908del p.S302Lfs*8 | Frame Shift Del (DEL) | VAF 250/315 reads (79%) | called by mutect2, pindel, varscan2
- TOPBP1 | c.4141dup p.I1381Nfs*11 | Frame Shift Ins (INS) | VAF 119/369 reads (32%) | called by mutect2, varscan2
- ACP5 | c.531C>T p.D177= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs369197756; called by muse, mutect2, varscan2
- ACSL6 | c.1419C>T p.G473= (on ENST00000379240; = p.G498= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as rs138919958; called by muse, mutect2, varscan2
- ARHGAP35 | c.4125C>T p.V1375= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as COSV68335229; called by muse, mutect2, varscan2
- ARHGEF17 | c.1323C>T p.G441= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV55236995; called by muse, mutect2, varscan2
- BEST2 | c.384C>A p.L128= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV50376428; called by muse, mutect2, varscan2
- BTNL9 | c.669C>T p.S223= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV59795603, COSV59798926; called by muse, mutect2, varscan2
- DIP2B | c.4030C>T p.L1344= | Silent (SNP) | VAF 23/224 reads (10%) | catalogued as COSV99999553; called by muse, mutect2, varscan2
- DNAH12 | c.906T>C p.D302= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV60858511; called by muse, mutect2, varscan2
- FIGNL2 | c.78G>A p.P26= | Silent (SNP) | VAF 46/109 reads (42%) | called by muse, mutect2, varscan2
- GATD1 | c.72G>A p.S24= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs778112640, COSV60593435; called by muse, mutect2, varscan2
- H3C3 | c.297C>T p.A99= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1339966276, COSV100778322; called by muse, mutect2
- KIAA0586 | c.3147C>T p.C1049= (on ENST00000619416 / NM_001244190.2; = p.C988= on NM_014749.5) | Silent (SNP) | VAF 87/212 reads (41%) | catalogued as COSV54181568; called by muse, mutect2, varscan2
- KIR3DL2 | c.609C>A p.P203= | Silent (SNP) | VAF 132/366 reads (36%) | catalogued as COSV54394979; called by muse, mutect2, varscan2
- KLHL38 | c.141C>T p.C47= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV58088780; called by muse, mutect2, varscan2
- MAN1C1 | c.1797C>T p.D599= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1164669599, COSV56048058; called by muse, mutect2, varscan2
- MYH4 | c.4434G>A p.S1478= | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as rs528647257, COSV55124832; called by muse, mutect2, varscan2
- MYPN | c.3130C>A p.R1044= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV62738293; called by muse, mutect2, varscan2
- PDE5A | c.558C>T p.S186= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as rs752952681, COSV53346187; called by muse, mutect2, varscan2
- SLC12A4 | c.240G>C p.S80= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as COSV57933466, COSV57934706; called by muse, mutect2, varscan2
- SLC16A1 | c.1164C>T p.S388= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63710192; called by muse, mutect2, varscan2
- SLC4A1 | c.1317G>A p.E439= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1287703923, COSV52262703; called by muse, mutect2, varscan2
- TNFAIP2 | c.1074C>T p.S358= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs377538302; called by muse, mutect2, varscan2
- TP53 | c.357C>G p.A119= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV52702653, COSV52827728; called by muse, mutect2, varscan2
- TTC7A | c.1188C>T p.Y396= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs749892467, COSV55408593; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT2B4 | c.277C>T p.L93= | Silent (SNP) | VAF 78/175 reads (45%) | catalogued as rs202090725, COSV59319978; called by muse, mutect2, varscan2
- ZNF394 | c.543A>G p.R181= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV61794400; called by muse, mutect2, varscan2
